TARGET case TARGET-15-SJMPAL042789 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ea745cd1-65be-4c67-8f34-3cd9656fd2c7

Demographics
Sex at birth: male; Age at index: 3 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 3.8 years (1,371 days); Year of diagnosis: 2010; Days to last follow up: 1,736 days (4.8 years).

Follow-up (1 entry)
- Days to follow up: 1,736 days (4.8 years); Event-free: no event (relapse, second malignancy or death) recorded through day 1,736; Year of follow up: 2014.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 0: Leukocytes 2.5 ×10³/µL.

Biospecimens (4 samples)
- Samples TARGET-15-SJMPAL042789-09A.1, TARGET-15-SJMPAL042789-09A.2, TARGET-15-SJMPAL042789-09A.3 (3 with the same recorded description): Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-15-SJMPAL042789-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 1736
- Protocol: Westmead
- WBC at Diagnosis: 2.5
- WHO ALAL Classification: NOS (T/B/M)
- WHO Dx: NOS (T/B/M)
